TCGA case TCGA-QG-A5Z1 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction; Tissue source site: BLN - Baylor. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9c45eaec-d854-4f51-80a3-2d80d6b4aebc

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Dead; Days to death: 256 days.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C19; Tissue or organ of origin: Rectosigmoid junction; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 71.8 years (26,220 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1b; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 256 days.
   Pathology details: Circumferential resection margin: 5; Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 38; Lymphatic invasion present: Yes; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 202 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 256.

Molecular and laboratory tests
- CEA: 5.3 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 91.1 kg.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QG-A5Z1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 190 mg.
  Slide TCGA-QG-A5Z1-01A-01-TS1: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-QG-A5Z1-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QG-A5Z1-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Colon; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 5.3; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No; New tumor event diagnosis indicator: No.
- Drug treatment: Pharmaceutical treatment ongoing indicator: No.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 256 days; disease-specific survival: no event (censored), 256 days; progression-free interval: no event (censored), 256 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QG-A5Z1-01A-11D-A28F-01): tumor purity 0.8, ploidy 2.07, whole-genome doublings 0.
